TCGA case TCGA-29-1764 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c70228cc-79c0-4c00-8926-6671c1474701

Demographics
Sex at birth: female; Race: white; Age at index: 49 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 49.3 years (18,012 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No; Days to last follow up: 1,914 days (5.2 years).
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 167 days; Number of cycles: 7; Treatment dose: 4,581 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 87 days; Number of cycles: 6; Treatment dose: 12,000 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 111 days; Days to treatment end: 167 days; Number of cycles: 3; Treatment dose: 1,050 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 797 days (2.2 years); Days to treatment end: 818 days (2.2 years); Number of cycles: 3; Treatment dose: 60 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 822 days (2.3 years); Days to treatment end: 968 days (2.7 years); Number of cycles: 8; Treatment dose: 590 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,301 days (3.6 years); Days to treatment end: 1,343 days (3.7 years); Number of cycles: 3; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,366 days (3.7 years); Days to treatment end: 1,515 days (4.1 years); Number of cycles: 6; Treatment dose: 80 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,785 days (4.9 years); Days to treatment end: 1,785 days (4.9 years); Number of cycles: 1; Treatment dose: 80 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,816 days (5.0 years); Days to treatment end: 1,973 days (5.4 years); Treatment dose: 1,100 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,816 days (5.0 years); Days to treatment end: 1,973 days (5.4 years); Number of cycles: 6; Treatment dose: 6 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 51.5 years (18,804 days); Days to diagnosis: 792 days (2.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 792 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 792 days (2.2 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,914 days (5.2 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Other.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1764-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-29-1764-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3.
  Slide TCGA-29-1764-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 12; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3.
- Sample TCGA-29-1764-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Topotecan HCL.
- Drug treatment 5: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,914 days; disease-specific survival: no event (censored), 1,914 days; disease-free interval: event (new tumor event after initially disease-free), 792 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 792 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-1764-01A-01D-0559-01): tumor purity 0.58, ploidy 3.48, whole-genome doublings 1.
